Surgical pathology report (de-identified scan), TCGA case TCGA-5B-A90C, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-5B-A90C-01A (Primary Tumor).

[page 1 of 7]
Results

SURG PATH FINAL REPORT

Service Location

Name

Address

Phone

Patient Information

Patient Name

Sex

DOB

Phone

Female

Result Notes

Notes Recorded by

RN on

Forwarded to for review.

ICD-O-3

Adenocarcinoma, endometrial

8386/3

Notes Recorded by

RN on

Site: Endometrium C54.1

Patient Release Status:

This result is not viewable by the patient.

JPW 1/21/14

Collection Information

Resulting Agency

Entry Date

Component Results

SURG PATH FINAL REPORT

Accession #:

Specimen:

Date of Procedure:

Performing Physician: M.D.

- A. Right pelvic lymph node
- B. Right periaortic lymph node
- C. Left pelvic lymph node
- D. Left periaortic lymph node
- E. Uterus, cervix, tubes, ovaries

Clinical Notes:

Endometrial cancer. Specimen E: Tissue to be sent for

Diagnosis:

- A. Right pelvic lymph node, excision:
- Negative for malignancy (0/13).
- B. Right periaortic lymph nodes, excision:

Printed by

[page 2 of 7]
- Negative for malignancy (0/10).
- C. Left pelvic lymph nodes, excision:
- Negative for malignancy (0/11).
- D. Left periaortic lymph nodes, excision:
- Negative for malignancy (0/8).
- E. Uterus, cervix, bilateral fallopian tubes, and ovaries, hysterectomy with bilateral salpingo-oophorectomy:
- Endometrial adenocarcinoma, endometrioid type FIGO grade 2 with focal mucinous differentiation.
- Please see Tumor Characteristics.
- AJCC stage: pT1a N0.

Note: Immunohistochemical stain for MSI is sent out (block E8).

[REDACTED] MD [REDACTED]
(Electronically signed by)
Verified: [REDACTED]

Tumor Characteristics:
E: Endometrium, Hysterectomy (AJCC 7th, 2010)

Accession #: [REDACTED]

MACROSCOPIC

SPECIMEN TYPE:

Uterine corpus
Cervix
Right ovary
Left ovary
Right fallopian tube
Left fallopian tube
Weight, uterus: 226 gm

PROCEDURE:

Simple hysterectomy
Bilateral salpingo-oophorectomy

SPECIMEN INTEGRITY:

Intact hysterectomy specimen

TUMOR SITE:

Anterior endometrium
Posterior endometrium

The tumor is exophytic as well as diffusely involving the anterior lower uterine segment and extends along the right lateral endometrial cavity to involve the majority of the posterior surface of the endometrial cavity.

[page 3 of 7]
TUMOR SIZE:
Greatest dimension: 7.0 x 6.0 x 2.5 cm
MICROSCOPIC
HISTOLOGIC TYPE:
Endometrioid adenocarcinoma
HISTOLOGIC GRADE [FIGO] (Grading system applies to
endometrioid / mucinous carcinoma):
FIGO II
MYOMETRIAL INVASION:
Invasion present
Specify depth of invasion: 0.4 cm
Specify myometrial thickness: 1.5 cm
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION:
Absent
PERINEURAL INVOLVEMENT:
Absent
CERVICAL EXTENSION:
Absent
Sections (3) of the anterior cervix show tumor aggregates
on the serosal surface and within cracks in the stroma. These
are presumed to be contaminants as there is no stromal
reaction to them
OVARIAN INVOLVEMENT:
Absent
SURGICAL MARGINS:
Uninvolved by invasive carcinoma
REGIONAL LYMPH NODES::
Right Pelvic
Number involved: 0

Accession #: [REDACTED]

Number examined: 13
Left Pelvic
Number involved: 0
Number examined: 11
Right Periaortic
Number involved: 0
Number examined: 10
Left Periaortic
Number involved: 0
Number examined: 8
ADDITIONAL PATHOLOGIC FINDINGS:
Hyperplasia: Complex (adenomatous)
Leiomyoma with calcifications
PRIMARY TUMOR (pT) TNM [FIGO]:
pT1a [IA]: Tumor limited to endometrium or invades less
than one-half of the myometrium
REGIONAL LYMPH NODES (pN) TNM [FIGO]:
pN0 [--]: No regional lymph node metastasis

[page 4 of 7]
PERITONEAL WASHINGS/ASCITIC FLUID:
Negative [REDACTED]

Gross:

A. The specimen is labeled "right pelvic lymph node."
Received in formalin is a 6.0 x 5.0 x 1.0 cm aggregate of
yellow-brown fibrofatty tissue. The specimen is examined
for lymph nodes. Twelve lymph node candidates are
identified ranging from 0.5 to 4.1 cm in greatest
dimension.
The largest is sectioned to reveal a solid, tan-white cut
surface. The nodal tissue is submitted entirely as
follows:

Cassette Designation:

	A1	Six lymph node candidates
	A2	Four lymph node candidates
bisected	A3	One lymph node candidate,
trisected	A4-6	One lymph node candidate,

B. The specimen is labeled "right periaortic lymph node."
Received in formalin is a 4.5 x 4.0 x 1.0 cm portion of
yellow-brown fibroadipose tissue. The specimen is examined
for lymph nodes. Five lymph node candidates are identified
ranging from 0.2 to 3.0 cm in greatest dimension. The
nodal
tissue is submitted entirely as follows:

Cassette Designation:

	B1	One lymph node candidate
	B2	Three lymph node candidates
trisected	B3-4	One lymph node candidate,

Accession #: [REDACTED]

C. The specimen is labeled "left pelvic lymph node."
Received in formalin is a 5.5 x 4.0 x 0.5 cm aggregate of
yellow-tan, lobulated fibroadipose tissue. The specimen is
examined for lymph nodes. Eleven lymph node candidates are
identified ranging from 0.2 to 1.5 cm in greatest
dimension.
The nodal tissue is submitted entirely as follows:

Cassette Designation:

bisected	C1	One lymph node candidate,
----------	----	---------------------------

[page 5 of 7]
C2 Five lymph node candidates
C3 Five lymph node candidates

D. The specimen is labeled "left periaortic lymph node." Received in formalin is a 6.0 x 3.0 x 1.0 cm portion of lobulated, yellow fibroadipose tissue. The specimen is examined for lymph nodes. Eight lymph node candidates are identified ranging from 0.5 to 3.0 cm in greatest dimension.

The nodal tissue is submitted entirely as follows:

Cassette Designation:

D1	Six nodal candidates
D2	One lymph node candidate, bisected
D3	One lymph node candidate, bisected

E. The specimen is labeled "uterus, cervix, tubes and ovaries." Received fresh for is a 226 gram uterus with attached left tube and right tube and ovary. The left ovary

is received separately within the container. The uterus is composed of a 7.5 cm long by 7.5 cm cornu to cornu by 6.0

cm anterior to posterior uterine body with an attached 5.0 cm long and 2.5 cm in diameter 3 to 9 o'clock by 2.0 cm in diameter 12 to 6 o'clock cervix. The uterine serosa is smooth, tan-gray to purple. The cervix is somewhat disrupted and fragmented resulting in an incomplete endocervical canal on the anterior aspect. A small amount of ectocervix is present which is smooth and tan-gray.

The 7.0 cm wide by 8.0 cm long triangular endometrial cavity

exhibits an exophytic, soft, friable, tan-gray mass. The mass is present within the anterior lower uterine aspect extending along the right lateral endometrial cavity to involve the majority of the posterior superior endometrial cavity. The mass is 6.0 x 6.0 x 2.5 cm in overall dimension. The mass does not involve the posterior lower uterine segment. The mass exhibits a polypoid component at the right cornu. The anterior superior endometrial cavity exhibits a flat, tan endometrial covering with a thickness of 0.1 cm. The mass is sectioned to reveal only grossly superficial mucosal involvement with no gross extension

into

Accession #: [REDACTED]

the underlying myometrium. The myometrium is pink-tan with a thickness ranging from 2.0 to 3.0 cm. The myometrium contains three well-circumscribed, white-gray, whorled

Printed by [REDACTED]

[page 6 of 7]
intramural nodules ranging from 0.5 to 4.0 cm in greatest dimension.

The left ovary is detached and is 3.5 x 3.0 x 0.6 cm. The outer surface is intact with a smooth, purple-tan capsule. Sectioning reveals a mottled, tan-gray unremarkable ovarian stroma. The attached 6.0 cm long fimbriated fallopian tube has a diameter of 0.5 cm and is sectioned to reveal a stellate patent lumen.

The right ovary is 4.5 x 2.5 x 1.0 cm and is intact with a tan-brown capsule. Sectioning reveals a homogeneous, mottled, gray-tan unremarkable ovarian stroma. The 5.0 cm long by 0.5 cm in diameter fimbriated fallopian tube is sectioned to reveal a stellate patent lumen.

Representative
sections are submitted as follows:

Cassette Designation:

E1	Left parametrial tissue
E2	Right parametrial tissue
E3	Anterior cervix
E4	Anterior lower uterine segment
E5-7	Anterior endomyometrium, including
mass, from inferior to superior	
E8-9	Polypoid portion of mass, bisected
E10	Posterior cervix
E11	Posterior lower uterine segment
E12-14	Posterior endomyometrium, with mass,
from inferior to superior	
E15	Additional myometrial nodule
E16	Left ovary
E17	Left fimbriated end of fallopian
tube, bisected longitudinally	
E18	Left fallopian tube cross sections
E19	Right ovary
E20	Fimbriated end of right fallopian
tube, bisected longitudinally	
E21	Cross sections of right fallopian
tube	
E22-23	Additional sections of anterior
cervix	

Gross photos are taken of the specimen.

Accession #: [REDACTED]

Printed by [REDACTED]

[page 7 of 7]
Encounter Date: [REDACTED]

Microscopic:

Histological examinations have been performed on specimens A-E.

x

Deeper sections x 2 are obtained on E3 and deeper sections 1 are obtained on E12 and E13.

Administrative Notes:

CPT:

No charge codes are associated with this case.

Results

Report, Other - Scan on [REDACTED] by [REDACTED]

Result History

SURG PATH FINAL REPORT ([REDACTED]) on [REDACTED] Order Result History Report.

Lab Information

Resulting Agency

Lab Collection Information

Collection Date and Time

IDs

Order #

Specimen #

MD on

RN on

RN on

RN on

RN on

Order

SURG PATH FINAL REPORT

Service Location

Name

Address

Phone

Patient Information

Patient Name

Sex

DOB

Phone

Female

Unit

Room

Encounter

Printed by

Source: NCI Genomic Data Commons file e58b3a0f-5279-4782-adcb-ce3b2d5dad92 (TCGA-5B-A90C.608E2698-6A3A-4673-89D2-3BE98A74EBE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).